MMRF case MMRF_2563 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b2fd8920-66d7-4496-991a-b79e2a50130e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.1 years (22,698 days); ISS stage: III; Days to last known disease status: 670 days (1.8 years); Days to last follow up: 670 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 299 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 167 days; Days to treatment end: 171 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 175 days; Days to treatment end: 175 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 238 days; Days to treatment end: 293 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 240 days; Days to treatment end: 300 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 342 days; Days to treatment end: 650 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 342 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 651 days (1.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 670.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 7.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.323 mg/dL; Immunoglobulin G 2.77 g/L; Immunoglobulin A 87.8 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 5.99 µg/mL; Lactate Dehydrogenase 1.32 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 13.7 mmol/L; Calcium 2.27 mmol/L; Albumin 22 g/L; Total Protein 11.7 g/dL; Glucose 6.6 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 75 (ECOG 1): M Protein 1.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.213 mg/dL; Immunoglobulin G 3.54 g/L; Immunoglobulin A 16.6 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.16 mmol/L; Albumin 30 g/L; Total Protein 6.4 g/dL; Glucose 4.4 mmol/L.
- Day 201 (ECOG 1): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.174 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.148 mg/dL; Immunoglobulin G 3.59 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.01 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.7 mmol/L; Calcium 1.91 mmol/L; Albumin 26 g/L; Total Protein 5.2 g/dL; Glucose 5.4 mmol/L.
- Day 271 (ECOG 0): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.376 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.298 mg/dL; Immunoglobulin G 3.63 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 59 ×10⁹/L; Creatinine 100 µmol/L; Calcium 2.16 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 3.8 mmol/L.
- Day 341 (ECOG 0): M Protein 4.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.867 mg/dL; Immunoglobulin G 7.92 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 106 µmol/L; Calcium 2.25 mmol/L; Albumin 40.6 g/L; Total Protein 6.2 g/dL; Glucose 3.4 mmol/L.
- Day 483 (ECOG 0): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 59 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 8.7 mmol/L; Calcium 2.2 mmol/L; Albumin 41.6 g/L; Total Protein 6.4 g/dL; Glucose 5.4 mmol/L.
- Day 539 (ECOG 0): M Protein 4.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.57 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 1.16 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 92 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.15 mmol/L; Albumin 37.3 g/L; Total Protein 6.5 g/dL; Glucose 5.3 mmol/L.
- Day 651 (ECOG 0): M Protein 4.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.53 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 51 ×10⁹/L; Creatinine 102 µmol/L; Calcium 2.23 mmol/L; Albumin 38.8 g/L; Total Protein 6.4 g/dL; Glucose 6.4 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 183 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2563_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2563_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
